TCGA case TCGA-G7-7501 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4afab224-f65e-48a8-8802-01138e210e29

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 624 days (1.7 years).

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.2 years (20,165 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T2a; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 624 days (1.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 12; Prcc type: Type 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sunitinib; Days to treatment start: 110 days; Days to treatment end: 506 days (1.4 years); Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 55.5 years (20,275 days); Days to diagnosis: 110 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Day 110 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 416 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 624 days (1.7 years); Disease response: With Tumor.
- Karnofsky performance status: 20; ECOG performance status: 4; Timepoint: Recurrence/Progression.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Leukocytes: Elevated.
- Hemoglobin: Low.
- Platelets: Elevated.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 156 cm; BMI: 23.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 17; Tobacco smoking onset year: 1978.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G7-7501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-G7-7501-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-G7-7501-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-G7-7501-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G7-7501-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 2.
- Drug treatment: Pharmaceutical therapy drug name: sutent; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 624 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 624 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 110 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G7-7501-01A-11D-2200-01): tumor purity 0.88, ploidy 1.79, whole-genome doublings 0.
